HCMI case HCM-EXPT-1212-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/40357899-a869-431e-8f60-20a7c69522ae

Demographics
Sex at birth: male; Days to birth: -23,193 days (63.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C25.3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreatic duct; Classification of tumor: primary; Uicc staging system edition: 7th.

Biospecimens (1 sample)
- Sample HCM-EXPT-1212-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
